Somatic mutation profile of tumor specimen PCProject_0187_T1_WES (aliquot PCProject_0187_T1_WES_1) from CMI case PCProject_0187, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.5 years (20,997 days).
Specimen PCProject_0187_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bab7c381-026a-4e2d-ba6b-ad6dc4b66072.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0187_BLOOD_BC (Blood Derived Normal), aliquot PCProject_0187_BLOOD_BC_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0eed9a6-d5c3-44a6-86f5-d21b4563653d

The open-access MAF lists 59 somatic variants for this specimen: 42 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 12, Intron 3, Splice Site 2, Nonsense Mutation 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSM5 | c.925C>T p.L309F | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); catalogued as rs763774602, COSV59374018; called by muse, mutect2, varscan2
- AR | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 35/58 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs868669253, COSV65953169; called by muse, mutect2, varscan2
- ARHGEF11 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1388884489, CM142294, COSV100168393; called by muse, mutect2, varscan2
- ASPA | c.290A>G p.N97S | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs763469507; called by muse, mutect2, varscan2
- DDX23 | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as rs1418397334, COSV57284916, COSV57286745; called by muse, mutect2, varscan2
- EXOC6 | c.1826T>C p.I609T | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs1357645301; called by muse, mutect2, varscan2
- GABRA5 | c.212G>A p.R71H | Missense Mutation (SNP) | VAF 72/429 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.75); catalogued as rs775162132, COSV100164665; called by muse, mutect2, varscan2
- GSC | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 118/451 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.5); catalogued as rs761638109; called by muse, mutect2, varscan2
- INO80D | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755323717; called by muse, mutect2, varscan2
- LPO | c.1739C>T p.T580I | Missense Mutation (SNP) | VAF 65/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs761419379; called by muse, mutect2, varscan2
- NSD2 | c.2359C>T p.R787C | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100372977, COSV56391740; called by muse, mutect2, varscan2
- PPFIBP1 | c.2536G>A p.V846I (on ENST00000318304 / NM_177444.3; = p.V840I on NM_003622.4) | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs539499516, COSV57299002; called by muse, mutect2, varscan2
- TNN | c.538C>T p.R180C | Missense Mutation (SNP) | VAF 62/383 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs895808761, COSV99511669; called by muse, mutect2, varscan2
- TSGA10 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs550646029; called by mutect2, varscan2
- TTN | c.72466G>A p.E24156K (on ENST00000591111; = p.E16732K on NM_003319.4) | Missense Mutation (SNP) | VAF 6/20 reads (30%) | PolyPhen benign (0.011); catalogued as rs753331124; called by muse, mutect2, varscan2
- WIPF3 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs754655046, COSV54210700; called by muse, mutect2, varscan2
- WNT8A | c.470G>C p.R157T | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1027317291; called by muse, mutect2
- ZFP42 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs1194173718; called by muse, mutect2, varscan2
- ZNF335 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs763235298, COSV59817298; called by muse, mutect2, varscan2
- ZNF730 | c.131-1G>T p.X44_splice | Splice Site (SNP) | VAF 65/144 reads (45%) | catalogued as COSV74168091; called by muse, mutect2, varscan2
- ABL1 | c.2505A>C p.E835D | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS20 | c.77T>G p.F26C | Missense Mutation (SNP) | VAF 12/229 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- ADM2 | c.292C>T p.P98S | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ALG12 | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 109/652 reads (17%) | PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ANK2 | c.9338G>A p.R3113Q | Missense Mutation (SNP) | VAF 63/212 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BOK | c.350-6_351del p.X117_splice | Splice Site (DEL) | VAF 33/101 reads (33%) | called by mutect2, pindel, varscan2
- CILK1 | c.848dup p.Y283* | Nonsense Mutation (INS) | VAF 56/200 reads (28%) | called by mutect2, pindel, varscan2
- EIF2AK4 | c.1635G>T p.M545I | Missense Mutation (SNP) | VAF 32/166 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- EYS | c.3175C>A p.L1059I | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HMCN1 | c.1319C>A p.P440Q | Missense Mutation (SNP) | VAF 124/239 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HTT | c.8006A>G p.H2669R | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- IRS2 | c.2486C>A p.P829H | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2, varscan2
- KRT73 | c.789A>C p.E263D | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LILRA6 | c.883A>G p.R295G | Missense Mutation (SNP) | VAF 99/678 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGI3 | c.611C>G p.P204R | Missense Mutation (SNP) | VAF 60/245 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- POLR3B | c.248G>C p.G83A | Missense Mutation (SNP) | VAF 93/182 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- PPID | c.14C>A p.S5Y | Missense Mutation (SNP) | VAF 94/419 reads (22%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- PSMD3 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 66/231 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SKOR1 | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (0.75); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRIM24 | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- USP10 | c.570T>G p.S190R | Missense Mutation (SNP) | VAF 88/301 reads (29%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- ZNF654 | c.253C>T p.L85F | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- G6PC2 | c.354C>T p.G118= | Silent (SNP) | VAF 47/338 reads (14%) | catalogued as rs185108752, COSV56371540; called by muse, mutect2, varscan2
- GDF7 | c.81C>T p.A27= | Silent (SNP) | VAF 23/87 reads (26%) | called by muse, mutect2, varscan2
- ITIH1 | c.1305C>T p.F435= | Silent (SNP) | VAF 57/200 reads (29%) | catalogued as rs780134438, COSV56257433; called by muse, mutect2, varscan2
- JADE1 | c.786G>A p.P262= | Silent (SNP) | VAF 49/148 reads (33%) | catalogued as rs1490185269; called by muse, mutect2, varscan2
- PMEPA1 | c.369C>T p.P123= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs766322769; called by muse, varscan2
- RIC1 | c.3303C>T p.A1101= | Silent (SNP) | VAF 42/222 reads (19%) | catalogued as rs753665520; called by muse, mutect2, varscan2
- RRP12 | c.1101C>T p.N367= | Silent (SNP) | VAF 70/325 reads (22%) | catalogued as rs753515335, COSV59668589; called by muse, mutect2, varscan2
- SOHLH1 | c.123G>A p.P41= | Silent (SNP) | VAF 84/261 reads (32%) | catalogued as rs778083451, COSV104404045; called by muse, mutect2, varscan2
- SPON1 | c.1434C>A p.V478= | Silent (SNP) | VAF 43/215 reads (20%) | catalogued as rs782007435; called by muse, mutect2, varscan2
- SUFU | c.294C>G p.L98= | Silent (SNP) | VAF 133/520 reads (26%) | called by muse, mutect2, varscan2
- WT1 | c.672G>A p.T224= | Silent (SNP) | VAF 69/443 reads (16%) | catalogued as rs756695525; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZFHX3 | c.3765C>T p.P1255= | Silent (SNP) | VAF 44/251 reads (18%) | called by muse, mutect2, varscan2
- AC010507.1 | chr19:200405 G>C | 3'Flank (SNP) | VAF 8/80 reads (10%) | called by muse, varscan2
- ADGRD1 | c.188-2439C>A | Intron (SNP) | VAF 19/211 reads (9%) | called by muse, mutect2
- BMS1P1 | n.2422A>C | RNA (SNP) | VAF 64/193 reads (33%) | called by muse, mutect2, varscan2
- NRXN1 | c.3245-926T>A | Intron (SNP) | VAF 22/124 reads (18%) | called by muse, mutect2, varscan2
- USP28 | c.535-966C>G | Intron (SNP) | VAF 51/152 reads (34%) | called by muse, mutect2, varscan2
